Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A45W, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A45W-01A (Primary Tumor).

[page 1 of 2]
DOB:

Sex: M

Physician:

Received:

Pathologist:

Accession:

Case type: Surgical History

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to the section "SPECIMEN" may have been added. ****

DIAGNOSIS

- (A) RIGHT SUPRAGLOTTIC LARYNX, BIOPSIES:
MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA.
- (B) LOWER MOST JUGULAR LYMPH NODE:
Two lymph nodes, no evidence of metastatic disease.
- (C) LOWER MOST RIGHT JUGULAR LYMPH NODE:
One lymph node, no evidence of metastatic disease.
- (D) TOTAL LARYNGECTOMY AND BILATERAL NECK DISSECTION:
INVASIVE, MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA OF THE RIGHT
SUPRAGLOTTIC LARYNX WITH EXTENSION INTO THE ANTERIOR COMMISSURE,
LEFT SUPRAGLOTTIC LARYNX AND EPIGLOTTIS, 2.5 X 2.0 X 1.5 CM.
RESECTION MARGINS FREE OF TUMOR.
Lymphovascular invasion not identified.
Focal severe dysplasia of squamous epithelium, right posterior
mucosal margin.
Twenty-eight right neck lymph nodes, no evidence of metastatic
disease, one level 1, fourteen, level 2, four level 3, and nine
level 5.
Seventeen left neck lymph nodes, no evidence of metastatic disease
(seven level 2, four level 3, and six level 5).
Thyroid gland, no diagnostic abnormality.
- (E) NEW MARGIN POSTERIOR CRICOID AREA:
Squamous mucosa, no diagnostic abnormality.
- (F) LEFT PYRIFORM SINUS:
Squamous mucosa, no diagnostic abnormality.

ICD-0-3

Carcinoma, squamous cell, NOS 8070/3

Site: larynx, NOS C32.9

MW

10/1/12

Entire report and diagnosis completed by:
Report released by:

GROSS DESCRIPTION

- (A) RIGHT SUPRAGLOTTIC LARYNX - Four fragments of tan-pink soft tissue, ranging from 0.4 to 0.7 cm in greatest dimension. The specimen is entirely submitted for frozen section examination as A1.
Also received are multiple irregular fragments of tan, soft tissue (0.9 x 0.8 x 0.3 cm in aggregate) which are entirely submitted as A2.
FS/DX: INVASIVE MODERATELY DIFFERENTIAL SQUAMOUS CARCINOMA.
- (B) LOWER MOST LEFT JUGULAR NODE - Two ovoid, tan nodes (0.6 and 0.7 in greatest dimension). Submitted in toto in B.
- (C) LOWER MOST RIGHT JUGULAR NODE - A tan ovoid node (1.0 x 0.6 x 0.5 cm). The specimen is bisected and submitted in toto in C.
- (D) TOTAL LARYNGECTOMY AND BILATERAL NECK DISSECTION - A laryngectomy specimen (8.0 x 5.0 x 4.0 cm) with attached bilateral neck contents (right 12.2 x 8.4 x 0.9 cm; left 11.3 x 6.7 x 0.8 cm) and unremarkable right thyroid

[page 2 of 2]
DOB:

Sex: M

Physician:

Received:

Pathologist:

Accession:

Case type: Surgical History

lobe (4.2 x 1.5 x 1.1 cm).

An exophytic soft, tan-gray to red-purple, 2.5 x 2.0 cm tumor is present in the right supraglottic region. The tumor extends into the right glottic region. The right infraglottic region is uninvolved. The tumor also crosses the midline and involves the left glottic area. The tumor has an overall thickness of 1.5 cm.

The epiglottic mucosa is focally red and roughened on the posterior aspect.

One 0.3 cm in diameter right level I lymph node is identified. Fourteen right level II lymph nodes are identified which range from 0.2 to 1.4 cm in greatest dimension. Four right level III lymph nodes are identified which range from 0.4 to 1.3 cm in greatest dimension. Nine, right level IV lymph nodes are identified which range from 0.2 to 1.1 cm in greatest dimension. Seven left level II lymph nodes are identified which range from 0.3 to 1.8 cm in greatest dimension. Four left level III lymph nodes are identified which range from 0.4 to 1.0 cm in greatest dimension. Six left level IV lymph nodes are identified which range from 0.2 to 0.6 cm in greatest dimension.

The nodal parenchyma of all of the lymph nodes is tan-pink to purple and soft. None are suspicious for metastatic disease grossly.

SECTION CODE: D1, left pyriform mucosal margin, en face, frozen section; D2, left aryepiglottic fold mucosal margin, en face, frozen section; D3, left anterior mucosal margin, en face, frozen section; D4, right anterior mucosal margin, en face, frozen section; D5, right aryepiglottic fold margin, en face, frozen section; D6, right pyriform mucosal margin, en face, frozen section; D7, right posterior mucosal margin, en face, frozen section; D8, left posterior mucosal margin, en face, frozen section; D9, tracheal mucosal margin, en face, frozen section; D10-D26, laryngeal tumor, sequentially sectioned from right to left, entirely submitted, (with midline portion in D24 and D25, and left portion in D26); D27, transglottic section, left; D28, epiglottis, representative sections; D29, thyroid, representative sections; D30, one right level I lymph node; D31, six right level II lymph nodes; D32, three right level II lymph nodes; D33, four right level II lymph nodes; D34, one right level II lymph node, bisected; D35, three right level III lymph nodes; D36, one right level III lymph node, bisected; D37, two right level IV lymph nodes; D38, four right level IV lymph nodes; D39, three right level IV lymph nodes; D40-D41, one left level II lymph node per cassette; D42, three left level III lymph nodes; D43, two left level II lymph nodes; D44, D45, one bisected left level III lymph node per cassette; D46, two left level III lymph nodes; D47, four left level IV lymph nodes; D48, two left level IV lymph nodes.

*FS/DX: FOCAL SEVERE DYSPLASIA OF SQUAMOUS EPITHELIUM OF RIGHT POSTERIOR MUCOSAL MARGIN. ALL OTHER MARGINS, NO TUMOR PRESENT.

(E) NEW MARGIN POST CRICOID AREA - A fragment of yellow-tan soft tissue (1.2 x 0.3 x 0.2 cm). The specimen is submitted in toto in E.

(F) LEFT PYRIFORM SINUS - A fragment of tan soft tissue (1.0 x 0.2 x 0.2 cm) The specimen is submitted in toto in F.

SNOMED CODES

M-80703 T-24100

Source: NCI Genomic Data Commons file 55b27c5b-2565-44b0-82e3-51daa02c4e42 (TCGA-CV-A45W.5625C3A8-81AB-4923-B556-0B55BF4AB407.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).